Somatic mutation profile of tumor specimen TCGA-S9-A7R2-01A (aliquot TCGA-S9-A7R2-01A-21D-A34J-08) from TCGA case TCGA-S9-A7R2, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 69.6 years (25,419 days).
Specimen TCGA-S9-A7R2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a76366cf-4e32-45c8-8db4-8eec07f05e11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7R2-10A (Blood Derived Normal), aliquot TCGA-S9-A7R2-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f022ecd-57a7-441a-a290-dcbeaf062209

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Nonsense Mutation 5, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 41/173 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, mutect2, varscan2
- ADAM2 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as COSV99697515; called by muse, mutect2, varscan2
- ALOX12 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs757126998, COSV52348911; called by muse, mutect2, varscan2
- CD300C | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100423266; called by muse, mutect2, varscan2
- CDCA7L | c.340T>G p.S114A | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100651124; called by muse, mutect2
- CKMT1A | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 20/93 reads (22%) | catalogued as rs150214356; called by muse, mutect2, varscan2
- CSN3 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs577013157, COSV59244659; called by muse, mutect2, varscan2
- DOCK11 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.089); catalogued as rs759076573, COSV52242394; called by muse, mutect2, varscan2
- EMB | c.180T>A p.H60Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.36); catalogued as COSV100296890; called by muse, mutect2, varscan2
- EPB41L2 | c.1586G>C p.S529T | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100440921; called by muse, varscan2
- EPM2AIP1 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 28/102 reads (27%) | catalogued as rs370683042; called by muse, mutect2, varscan2
- FAM47C | c.2978T>C p.M993T | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100792707; called by muse, mutect2, varscan2
- FLG | c.5395G>T p.D1799Y | Missense Mutation (SNP) | VAF 61/500 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100911673, COSV64240228; called by muse, mutect2, varscan2
- GRIN1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100160405; called by muse, mutect2, varscan2
- HMGCLL1 | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV99232448; called by mutect2, varscan2
- KIAA1109 | c.3068G>A p.C1023Y | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99165689; called by muse, mutect2, varscan2
- KRT2 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1281231362, COSV100548520; called by muse, mutect2, varscan2
- LRRC7 | c.1677G>T p.Q559H (on ENST00000651989 / NM_001370785.2; = p.Q526H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV99224310, COSV99227682; called by muse, mutect2, varscan2
- LTBP1 | c.1379C>G p.S460* (on ENST00000404816 / NM_206943.4; = p.S134* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100617366; called by muse, mutect2, varscan2
- NAA25 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV55702028; called by muse, mutect2, varscan2
- OR4K13 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100237768; called by muse, mutect2
- PCM1 | c.2867A>G p.N956S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs747835063, COSV61518687; called by muse, mutect2
- PTPN14 | c.2466A>T p.K822N | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100872704; called by muse, mutect2, varscan2
- RALGAPA1 | c.2959G>T p.E987* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99355124; called by muse, mutect2, varscan2
- SPATA31A1 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 126/543 reads (23%) | catalogued as rs1388438641; called by muse, mutect2, varscan2
- TBC1D10A | c.1499C>G p.S500C | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV99304706; called by muse, mutect2, varscan2
- UGT2A1 | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs1270699532, COSV99684507; called by muse, mutect2, varscan2
- ZNF479 | c.1268C>A p.T423N | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100482810; called by muse, mutect2, varscan2
- ZNF479 | c.56G>C p.R19T | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs768039689, COSV100482811; called by muse, mutect2, varscan2
- RBMY1E | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by mutect2, varscan2
- UTRN | c.4047G>C p.L1349F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, varscan2
- ATF6B | c.483C>G p.V161= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100916838; called by muse, mutect2, varscan2
- CDYL2 | c.1047C>T p.I349= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs201151824, COSV73655103; called by muse, mutect2, varscan2
- FSTL1 | c.540T>C p.N180= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as COSV99820753; called by muse, mutect2, varscan2
- HECW1 | c.4431C>T p.A1477= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV101223855; called by muse, mutect2, varscan2
- ICE1 | c.4347T>A p.P1449= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99664983; called by muse, mutect2, varscan2
- MYO5C | c.2595C>T p.Y865= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs759970309, COSV55906085, COSV55913323; called by muse, mutect2, varscan2
- OR4C6 | c.732G>T p.V244= | Silent (SNP) | VAF 50/200 reads (25%) | catalogued as COSV100051682; called by muse, mutect2, varscan2
- RGS22 | c.3504C>T p.D1168= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs372450445; called by muse, mutect2, varscan2
- SIPA1L1 | c.951A>G p.R317= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100665662; called by muse, mutect2, varscan2
- ZAN | c.1965C>T p.T655= | Silent (SNP) | VAF 35/202 reads (17%) | catalogued as rs370829788, COSV100769837, COSV100770069; called by muse, mutect2, varscan2
- AGAP2 | chr12:57742020 G>A | 5'Flank (SNP) | VAF 432/553 reads (78%) | catalogued as rs760716939, COSV99223516; called by muse, mutect2, varscan2
